CCDI case PBCAIK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a46dcc37-8bfc-4032-9b42-3bbce2bddcf3

Demographics
Sex at birth: male.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.9 years (2,513 days).

Biospecimens (3 samples)
- Sample 0DMWTL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMWTR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DMWTX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
